Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A8OO, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A8OO-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

Right pleura, right lower lobe of lung, and portion of chest wall; en bloc resection:

Tumor Characteristics:

1. Histologic type: Synovial sarcoma, predominantly poorly differentiated, see comment.
2. Histologic grade: High-grade.
3. Tumor site: Right visceral and parietal pleura.
4. Tumor size: 15.2 x 12.3 x 5.0 cm.
5. Microscopic extent of tumor: Tumor extends into right lower lobe of lung and superficially into the soft tissue of the parietal pleura. There is no deep chest wall soft tissue or bone invasion.
6. Mitotic rate: Up to 31 mitotic figures/ 10 hpf.
7. Necrosis: Present, approximately 10%.
8. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Lung resection margin: Negative for malignancy.
2. Chest wall margins:
- a. Deep soft tissue: Negative for malignancy.
- b. Peripheral soft tissue: Negative for malignancy.
- c. Rib bone margins: Negative for malignancy.

Lymph Node Status:

1. Total number of lymph nodes received: 0.

Other:

1. Other significant findings: None.

ICD-O.3

Sarcoma, synovial NOS 9040/3

Site Chest NOS C49.3

Pleura NOS C38.4

QW 5/1/14

Electronic Signature:

COMMENTS:

The background morphology is of a monophasic spindle cell type of synovial sarcoma. Approximately 75% of the tumor shows hypercellularity, increased nuclear atypia, greater than 2 mitotic figures per hpf, and patchy round cell features consistent with a poorly differentiated type of synovial sarcoma.

Immunohistochemical stains show that the tumor cells are positive for BCL2 and CD99. Only rare cells stain for EMA. The cells are negative for AE1/3, pankeratin, CK7, CD34, S100, Melan A, calretinin, WT1, pan muscle actin, desmin, and myogenin.

Per outside report a preoperative biopsy was sent to [REDACTED] where a diagnosis of synovial sarcoma was confirmed by [REDACTED] gene rearrangement by FISH in 85% of cells. I confirmed this in a phone conversation with Dr. [REDACTED]

CLINICAL HISTORY:

Preoperative Diagnosis: year old female with synovial cell sarcoma

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right pleural tumor end block chest wall

GROSS DESCRIPTION:

Received in a container of formalin labeled right pleural tumor with end block chest wall, is a 16.0 x 19.0 x 7.8 cm chest wall resection consisting of an 18.0 x 16.5 x 5.5 cm portion of lung with five attached ribs ranging from 9.8 cm long by 1.2 cm in width to 19.8 cm long by 1.7 cm in width. The anterior rib surfaces are inked blue. The lung gives rise to a focal pleural defect with an underlying, ill defined, 15.2 x 12.3 x 5.0 cm shaggy, orange-tan tumor. The identifiable pleural surfaces surrounding the tumor are inked black. At one aspect of the lung, there is a 13.0 cm long stapled resection margin. The staples are removed and the underlying parenchyma is inked blue. On section, tumor extends to within 1.0 cm of the nearest lung

[page 2 of 2]
stapled resection margin. On section, tumor involves pleura which is focally adherent to the attached rib. On section, tumor does not involve the ribs or the rib resection margin. Sections are submitted for in three cassettes labeled Representative sections are submitted in cassettes labeled as follows: A1-A2--representative tumor to inked pleura; A3-A4--tumor to adjacent lung parenchyma; A6--tumor to nearest lung resection margin; A7--representative of remaining lung resection margin; A8-A10--tumor to adjacent rib following decalcification; A11-A12--rib resection margins from one side; A13-A14--rib resection margins from opposite side (A11-A14 following decalcification).

MICROSCOPIC EXAMINATION:

There is focal tumor present on the soft tissue surface in a section of a rib margin, which I consider carryover artifact.

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 700d7ae2-8fcb-4ea4-bcbf-6dd8998c89f3 (TCGA-FX-A8OO.D0DE7E4F-BA40-4894-9A56-6ACE020DBC84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).